Somatic mutation profile of tumor specimen TCGA-D3-A3C7-06A (aliquot TCGA-D3-A3C7-06A-11D-A196-08) from TCGA case TCGA-D3-A3C7, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 57.4 years (20,979 days).
Specimen TCGA-D3-A3C7-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3570b4b9-d0e5-4fdf-9520-4026f2fcad26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A3C7-10A (Blood Derived Normal), aliquot TCGA-D3-A3C7-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca04b183-3d7d-4966-bd68-500e9eadbe55

The open-access MAF lists 1,115 somatic variants for this specimen: 749 protein-altering or splice-affecting, 338 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 679, Silent 338, Nonsense Mutation 47, RNA 12, Splice Site 11, Intron 10, Splice Region 8, 5'Flank 2, In Frame Del 2, 3'UTR 2, Frame Shift Ins 1, 5'UTR 1.

Variants (750 of 1,115; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/133 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL4A3 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs184730597, CM1414109, COSV67413256; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- IDS | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs193302910, CM128186, COSV61711433; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.6562C>T p.R2188* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as rs200497972, COSV63281417; ClinVar: pathogenic; called by mutect2, varscan2
- SLC27A5 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 23/48 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202081924, COSV54017957; called by muse, mutect2, varscan2
- TP63 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as rs900140738, COSV53196111; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs746195619, COSV59383506; called by muse, mutect2, varscan2
- A4GALT | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1178905875, COSV50744058; called by muse, mutect2, varscan2
- AADACL2 | c.577A>G p.N193D | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV62929664; called by muse, mutect2, varscan2
- ABCA13 | c.2011C>T p.P671S | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70026142; called by muse, mutect2, varscan2
- ABCB1 | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55945144; called by muse, mutect2, varscan2
- ABCC6 | c.1518G>A p.W506* | Nonsense Mutation (SNP) | VAF 24/58 reads (41%) | catalogued as rs1567513399, COSV52741674; called by muse, mutect2, varscan2
- ABI3BP | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.091); catalogued as COSV52529577; called by muse, mutect2, varscan2
- ABRA | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV61731978; called by muse, varscan2
- ACSS1 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs778468718, COSV60217987; called by muse, mutect2, varscan2
- ADAMTS20 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV67125970; called by mutect2, varscan2
- ADAMTS9 | c.3947C>T p.P1316L | Missense Mutation (SNP) | VAF 113/186 reads (61%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV55776108; called by muse, mutect2, varscan2
- ADGRE1 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1366583656, COSV51672721, COSV99165755; called by muse, mutect2, varscan2
- ADGRG4 | c.4241C>T p.S1414L | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV54950738; called by muse, mutect2, varscan2
- ADGRV1 | c.3697C>T p.P1233S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV101316173, COSV67979482; called by muse, mutect2, varscan2
- ADGRV1 | c.7612T>A p.F2538I | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67979484; called by mutect2, varscan2
- ADGRV1 | c.9997G>A p.E3333K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV67979488; called by muse, mutect2
- AHNAK2 | c.9047C>T p.S3016F | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV60909057; called by muse, mutect2, varscan2
- AK8 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53751099; called by muse, mutect2, varscan2
- AKAP4 | c.2516G>A p.G839E | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1269014457, COSV62073821; called by muse, mutect2, varscan2
- AKAP4 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 98/249 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.367); catalogued as COSV62073825; called by muse, mutect2, varscan2
- AKAP9 | c.3518A>G p.K1173R | Missense Mutation (SNP) | VAF 52/92 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as COSV62340013; called by muse, mutect2, varscan2
- ALAS1 | c.1844C>T p.P615L | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59626978; called by muse, mutect2, varscan2
- ALDH18A1 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100973137; called by muse, mutect2, varscan2
- ALDH18A1 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100973138; called by muse, mutect2, varscan2
- ALG13 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV52635758; called by muse, mutect2, varscan2
- ALK | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.331); catalogued as rs754823963, COSV66559060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX12B | c.229T>A p.F77I | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV59871393; called by muse, varscan2
- ALPP | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1229304863, COSV67395766; called by muse, mutect2, varscan2
- AMDHD1 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV57137932; called by muse, mutect2, varscan2
- AMER3 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs775305041, COSV100366877, COSV58465397; called by mutect2, varscan2
- AMHR2 | c.654G>A p.W218* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV57685020; called by muse, mutect2, varscan2
- ANK3 | c.8407G>A p.D2803N | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as COSV55044895; called by muse, mutect2, varscan2
- ANK3 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99779439; called by muse, mutect2, varscan2
- ANKFN1 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV59441941; called by muse, mutect2, varscan2
- ANKH | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.089); catalogued as COSV52477674; called by muse, mutect2, varscan2
- ANKRD12 | c.1885C>T p.H629Y | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.25); catalogued as rs1362240293, COSV50819340; called by muse, mutect2, varscan2
- ANO2 | c.278G>A p.R93K (on ENST00000356134 / NM_001278597.3; = p.R97K on NM_001278596.3) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as COSV100500495; called by mutect2, varscan2
- AOC1 | c.2221C>T p.P741S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV62870910; called by muse, mutect2, varscan2
- AOC1 | c.2222C>T p.P741L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs1426691898, COSV100710725, COSV62866876; called by muse, mutect2, varscan2
- AP1M1 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV52225074; called by muse, mutect2, varscan2
- APMAP | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99468438; called by muse, mutect2, varscan2
- APOB | c.7945G>A p.E2649K | Missense Mutation (SNP) | VAF 209/553 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as COSV51925442; called by muse, mutect2, varscan2
- APOBR | c.2965C>T p.P989S (on ENST00000431282; = p.P998S on NM_018690.4) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.621); catalogued as COSV60490062; called by muse, mutect2, varscan2
- APOBR | c.2966C>T p.P989L (on ENST00000431282; = p.P998L on NM_018690.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100112433, COSV60489025; called by mutect2, varscan2
- APOC4 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 168/407 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.153); catalogued as rs1384269297, COSV52989951, COSV52990586; called by muse, mutect2, varscan2
- APPBP2 | c.1705G>T p.E569* | Nonsense Mutation (SNP) | VAF 62/162 reads (38%) | catalogued as COSV50025950; called by mutect2, varscan2
- ARAF | c.683A>T p.D228V | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as COSV51691432; called by muse, mutect2, varscan2
- ARHGAP6 | c.2197G>A p.D733N (on ENST00000337414 / NM_013427.3; = p.D530N on NM_013423.3) | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs771155355, COSV57292292; called by muse, mutect2, varscan2
- ARHGEF16 | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.914); catalogued as COSV65681440; called by muse, mutect2, varscan2
- ARHGEF26 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754708272, COSV62843732; called by mutect2, varscan2
- ARHGEF5 | c.2698C>T p.P900S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV99282731; called by mutect2, varscan2
- ARHGEF6 | c.89T>G p.F30C | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51687957; called by muse, mutect2, varscan2
- ARHGEF9 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.253); catalogued as COSV53635183; called by muse, varscan2
- ARMC2 | c.1849C>T p.H617Y | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV100933522; called by mutect2, varscan2
- ARMC4 | c.2253G>A p.K751= | Splice Region (SNP) | VAF 26/42 reads (62%) | catalogued as rs753480648, COSV59457575; called by muse, mutect2, varscan2
- ART3 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.848); catalogued as COSV61913204; called by muse, mutect2, varscan2
- ASAH2 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368660971, COSV61482883; called by muse, mutect2, varscan2
- ASTN1 | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as rs1437442297, COSV56062601; called by muse, mutect2, varscan2
- ATAD5 | c.4628G>A p.S1543N | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV58972386; called by muse, mutect2, varscan2
- ATN1 | c.36G>T p.M12I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as COSV63110340; called by muse, mutect2, varscan2
- ATP9A | c.2476C>T p.R826W | Missense Mutation (SNP) | VAF 88/212 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs747242556, COSV58763792; called by muse, mutect2, varscan2
- ATXN7L2 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 95/258 reads (37%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.979); catalogued as COSV63992104; called by muse, mutect2, varscan2
- AVEN | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 27/74 reads (36%) | catalogued as rs879214057, COSV60732480; called by muse, mutect2, varscan2
- B3GLCT | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1297462394, COSV58453633; called by muse, mutect2, varscan2
- BCLAF1 | c.1160A>G p.K387R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV62140753; called by mutect2, varscan2
- BCS1L | c.101A>G p.K34R | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.105); catalogued as COSV55306179; called by muse, mutect2, varscan2
- BDP1 | c.7267T>A p.F2423I | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as COSV62429226; called by mutect2, varscan2
- BEND7 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 47/68 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV61987575; called by muse, mutect2, varscan2
- BICD1 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200444584, COSV55675339; called by muse, mutect2, varscan2
- BLK | c.1029+2T>C p.X343_splice | Splice Site (SNP) | VAF 19/30 reads (63%) | catalogued as COSV52049794; called by muse, mutect2, varscan2
- BRAP | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV58160205; called by mutect2, varscan2
- BRAP | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV100554086; called by muse, mutect2, varscan2
- BRF1 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs775546215, COSV100527164; called by muse, mutect2, varscan2
- BRF1 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100527168; called by muse, mutect2, varscan2
- BSND | c.904G>A p.G302R | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV64870295; called by muse, mutect2, varscan2
- BTBD1 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.404); catalogued as rs1257487844, COSV55601944; called by muse, mutect2, varscan2
- BTBD11 | c.2695C>T p.P899S (on ENST00000280758 / NM_001018072.2; = p.P436S on NM_001017523.2) | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV55018312; called by muse, mutect2, varscan2
- C12orf40 | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1339241267, COSV100210773, COSV61129811; called by muse, mutect2, varscan2
- C19orf33 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.23); catalogued as COSV56649773; called by muse, mutect2, varscan2
- C1orf87 | c.1445A>G p.E482G | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267598677, COSV64596230; called by muse, mutect2, varscan2
- C5AR1 | c.540G>C p.E180D | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT tolerated (0.95); PolyPhen benign (0.023); catalogued as COSV61892197, COSV61893689; called by muse, mutect2, varscan2
- C5orf49 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.547); catalogued as COSV67708064; called by muse, mutect2, varscan2
- C6 | c.2381G>A p.S794N | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.403); catalogued as rs1386759149, COSV54706156; called by muse, mutect2, varscan2
- C8B | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV64776531; called by muse, mutect2, varscan2
- C9orf135 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV65874653; called by muse, mutect2, varscan2
- CACHD1 | c.3218C>T p.P1073L | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51549157; called by muse, mutect2, varscan2
- CACNA1A | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64191217; called by muse, mutect2
- CACNA1B | c.5167C>T p.P1723S | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV53116059; called by muse, mutect2, varscan2
- CACNA1E | c.4558G>A p.V1520M | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as COSV62383995; called by muse, mutect2, varscan2
- CACNA1G | c.6163C>T p.R2055W | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs376936316, COSV100661926; called by mutect2, varscan2
- CACNA2D2 | c.1260+1G>A p.X420_splice | Splice Site (SNP) | VAF 15/32 reads (47%) | catalogued as COSV56560968; called by muse, mutect2, varscan2
- CADM2 | c.1190G>A p.G397E (on ENST00000407528 / NM_001167674.2; = p.G399E on NM_153184.4) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67359568; called by muse, mutect2, varscan2
- CADM3 | c.801G>A p.W267* (on ENST00000368125 / NM_001127173.3; = p.W301* on NM_021189.5) | Nonsense Mutation (SNP) | VAF 20/77 reads (26%) | catalogued as COSV63684189; called by muse, mutect2, varscan2
- CAMTA1 | c.1496G>A p.G499E | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57884408; called by muse, mutect2, varscan2
- CAPN10 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201800700, COSV54375044; called by muse, mutect2, varscan2
- CATSPER2 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 123/370 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58660321; called by muse, mutect2, varscan2
- CATSPERB | c.3062C>T p.S1021F | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56422808; called by muse, mutect2, varscan2
- CCAR1 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV56267814; called by muse, mutect2, varscan2
- CCDC146 | c.1512A>T p.K504N | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV53544679; called by muse, mutect2, varscan2
- CCDC42 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs369756851; called by mutect2, varscan2
- CCIN | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs760408110, COSV58724166; called by muse, mutect2, varscan2
- CCR2 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 138/362 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.612); catalogued as COSV52747831; called by muse, mutect2, varscan2
- CCR3 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100656445; called by muse, mutect2, varscan2
- CCR3 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100656446; called by muse, mutect2, varscan2
- CD1C | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as COSV63805802; called by muse, mutect2, varscan2
- CD1E | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as COSV63770191, COSV63770259; called by muse, mutect2, varscan2
- CD53 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.97); catalogued as COSV54760234; called by mutect2, varscan2
- CD6 | c.1781C>T p.S594F | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as rs867165482, COSV57836111; called by muse, mutect2, varscan2
- CD96 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV51913310; called by muse, mutect2, varscan2
- CDCA7 | c.482G>A p.R161K (on ENST00000347703 / NM_145810.3; = p.R240K on NM_031942.5) | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); catalogued as rs1267714326, COSV60719937; called by muse, mutect2, varscan2
- CDH20 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53005454; called by muse, mutect2, varscan2
- CDH23 | c.2729A>T p.Y910F | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54925955; called by muse, mutect2, varscan2
- CDH24 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV57460642; called by muse, varscan2
- CDH6 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762277349, COSV54065160; called by muse, mutect2, varscan2
- CDH6 | c.1313G>A p.G438D | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54065168; called by muse, mutect2, varscan2
- CDK19 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60447299; called by muse, mutect2, varscan2
- CDK5R2 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV56935639; called by muse, mutect2, varscan2
- CEACAM16 | c.1052A>T p.Y351F | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV69186285; called by muse, varscan2
- CECR2 | c.3409C>T p.P1137S (on ENST00000342247 / NM_001290047.2; = p.P953S on NM_001290046.1) | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs1215564397, COSV52837180; called by muse, mutect2, varscan2
- CELSR2 | c.5506C>T p.P1836S | Missense Mutation (SNP) | VAF 180/494 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54767731; called by muse, mutect2, varscan2
- CENPF | c.6761C>T p.S2254F | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.813); catalogued as COSV65273070; called by muse, mutect2, varscan2
- CENPI | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as rs758210239, COSV54501025; called by muse, mutect2, varscan2
- CEP128 | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV53672817; called by muse, mutect2, varscan2
- CEP76 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs754183790, COSV50865624; called by mutect2, varscan2
- CFAP57 | c.1123-1G>A p.X375_splice | Splice Site (SNP) | VAF 60/150 reads (40%) | catalogued as COSV63016657; called by muse, mutect2, varscan2
- CFHR1 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV57626219; called by muse, mutect2, varscan2
- CGAS | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV64807804; called by muse, mutect2, varscan2
- CHRNA2 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1173060055, COSV53556595; called by muse, mutect2, varscan2
- CHRNB4 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV55714910; called by muse, mutect2, varscan2
- CIR1 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV59595313; called by muse, mutect2, varscan2
- CLCNKA | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV58890607; called by muse, mutect2, varscan2
- CLEC16A | c.2612C>T p.S871F | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV55488681; called by muse, mutect2, varscan2
- CLEC4E | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV100222699, COSV55225075; called by muse, mutect2, varscan2
- CLGN | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1402134841, COSV57773407; called by muse, mutect2, varscan2
- CLSPN | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99230701; called by muse, mutect2, varscan2
- CNOT1 | c.6793C>T p.L2265F | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54699347; called by muse, mutect2, varscan2
- CNTNAP2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV62149914, COSV62264516; called by muse, varscan2
- CNTNAP2 | c.3176A>C p.K1059T | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV62149917; called by muse, varscan2
- COL11A1 | c.2531G>A p.G844E | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100616002; called by muse, mutect2, varscan2
- COL11A2 | c.4096G>A p.G1366S (on ENST00000341947 / NM_080680.3; = p.G1259S on NM_080679.2) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100553767; called by muse, mutect2, varscan2
- COL13A1 | c.1456G>A p.E486K (on ENST00000398978 / NM_001130103.2; = p.E429K on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100637749, COSV62570365; called by muse, mutect2, varscan2
- COL19A1 | c.1026G>A p.K342= | Splice Region (SNP) | VAF 21/52 reads (40%) | catalogued as rs777084943, COSV59566787; called by muse, mutect2, varscan2
- COL3A1 | c.1826G>A p.G609E | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58582876; called by muse, mutect2, varscan2
- COL5A2 | c.3634G>A p.G1212S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1486324773, COSV66407599; called by muse, mutect2, varscan2
- COL5A2 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as rs142312726, COSV66412010; called by mutect2, varscan2
- COL7A1 | c.3061G>A p.G1021S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV60391893; called by mutect2, varscan2
- CPA6 | c.599G>A p.W200* | Nonsense Mutation (SNP) | VAF 33/84 reads (39%) | catalogued as COSV52722060; called by muse, mutect2, varscan2
- CPED1 | c.2843G>A p.G948E | Missense Mutation (SNP) | VAF 102/187 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59997999; called by muse, mutect2, varscan2
- CPLX4 | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs986597829, COSV55313008; called by mutect2, varscan2
- CPS1 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV51803461; called by muse, mutect2, varscan2
- CRB1 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs937362854, COSV66328905; called by muse, mutect2, varscan2
- CREB3L4 | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs186543132, COSV55131512; called by mutect2, varscan2
- CYP11A1 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.228); catalogued as COSV51430831; called by muse, mutect2, varscan2
- CYP2E1 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV53312432; called by muse, mutect2, varscan2
- CYP2S1 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59505076; called by muse, mutect2, varscan2
- CYP4F8 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs768693886, COSV57853310; called by muse, mutect2, varscan2
- DBX2 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV60336407; called by muse, mutect2, varscan2
- DCAF16 | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 82/286 reads (29%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.092); catalogued as COSV66384068; called by muse, mutect2, varscan2
- DCAF5 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1230396454, COSV58458722; called by muse, mutect2, varscan2
- DCTN5 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV55614820; called by muse, mutect2, varscan2
- DCUN1D5 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs774048924, COSV52783895; called by mutect2, varscan2
- DDO | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64469738; called by muse, varscan2
- DDR1 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs147485952; called by muse, mutect2, varscan2
- DDX24 | c.1907T>C p.L636P | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.53); catalogued as COSV58211895; called by muse, mutect2, varscan2
- DEFB118 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV53619769; called by muse, mutect2, varscan2
- DGKG | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV53962083; called by muse, mutect2, varscan2
- DIAPH3 | c.2597C>T p.S866F (on ENST00000400324 / NM_001042517.2; = p.S603F on NM_030932.3) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.9); catalogued as COSV57365626; called by muse, mutect2, varscan2
- DISP2 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs148317482; called by muse, varscan2
- DLGAP2 | c.2248G>T p.E750* | Nonsense Mutation (SNP) | VAF 8/11 reads (73%) | catalogued as COSV70094887; called by mutect2, varscan2
- DMKN | c.284T>C p.L95S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV60084960; called by muse, mutect2, varscan2
- DNAH1 | c.10418C>T p.S3473F | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70226877; called by muse, mutect2, varscan2
- DNAH11 | c.1921G>A p.V641I | Missense Mutation (SNP) | VAF 107/189 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1455285040, COSV100178644; called by muse, mutect2, varscan2
- DNAH11 | c.1922T>A p.V641D | Missense Mutation (SNP) | VAF 105/185 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100178646; called by muse, mutect2, varscan2
- DNAH11 | c.2315A>T p.K772I | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV60942451; called by mutect2, varscan2
- DNAH17 | c.10471G>A p.E3491K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs752894740, COSV67750374; called by muse, mutect2
- DNAH17 | c.6880C>T p.L2294F | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV67750376; called by muse, mutect2, varscan2
- DNAH3 | c.11588T>A p.L3863* | Nonsense Mutation (SNP) | VAF 72/167 reads (43%) | catalogued as COSV54506717; called by muse, mutect2, varscan2
- DNAH5 | c.5396C>T p.S1799L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs727503903, COSV54207512; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.2530C>T p.P844S | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as rs765491656, COSV54207524, COSV54227173; called by muse, mutect2, varscan2
- DNAH6 | c.1564C>T p.Q522* | Nonsense Mutation (SNP) | VAF 50/131 reads (38%) | catalogued as COSV52851226; called by muse, mutect2, varscan2
- DNAH7 | c.9320C>T p.P3107L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV56754056, COSV56767163; called by muse, mutect2, varscan2
- DNAH8 | c.7178C>T p.T2393I | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV100544421; called by muse, mutect2, varscan2
- DNAH8 | c.9610G>A p.D3204N | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs867281706, COSV59429139, COSV59478340; called by muse, mutect2, varscan2
- DNM3 | c.947A>T p.N316I | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs764019043, COSV62453865; called by muse, mutect2, varscan2
- DPYD | c.887G>A p.G296D | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs672601284, COSV100928905; ClinVar: not provided; called by muse, mutect2, varscan2
- DPYD | c.886G>A p.G296S | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs1017935743, COSV100928906; called by muse, mutect2, varscan2
- DPYS | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV60906756; called by muse, mutect2, varscan2
- DRP2 | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV65809399, COSV65809898; called by muse, mutect2, varscan2
- DSC1 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs267605152, COSV57142434; called by mutect2, varscan2
- DSCAM | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.398); catalogued as COSV68021894, COSV68032898; called by muse, mutect2
- DSCAM | c.70C>T p.L24F | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV68627921, COSV68651604; called by muse, mutect2, varscan2
- DSG3 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1568087307, COSV57124556; called by muse, mutect2, varscan2
- DSPP | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV56808438; called by mutect2, varscan2
- DUSP3 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs376755368; called by muse, mutect2, varscan2
- EFCAB6 | c.4037C>T p.S1346F | Missense Mutation (SNP) | VAF 88/124 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV99413116; called by muse, mutect2, varscan2
- EGFLAM | c.829-1G>A p.X277_splice | Splice Site (SNP) | VAF 16/34 reads (47%) | catalogued as rs757058312, COSV100379752, COSV59294262; called by muse, mutect2, varscan2
- EHD2 | c.1562G>A p.G521E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54407042; called by muse, mutect2
- EIF4E2 | c.185T>A p.F62Y | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV51471238; called by muse, mutect2, varscan2
- EIF5B | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV56811418; called by muse, mutect2, varscan2
- ELOA2 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs995020698, COSV55294440, COSV55311281; called by muse, mutect2, varscan2
- ELOA2 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.054); catalogued as COSV55294449; called by muse, mutect2, varscan2
- ELSPBP1 | c.499T>A p.F167I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV60413007; called by mutect2, varscan2
- EML5 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 61/165 reads (37%) | catalogued as COSV61342459; called by muse, mutect2, varscan2
- ENTPD1 | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as COSV64600272; called by muse, mutect2, varscan2
- EPB41L2 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.293); catalogued as COSV61353638; called by muse, mutect2, varscan2
- EPHA3 | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV60695883; called by muse, mutect2, varscan2
- EPHA6 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 103/253 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67561265; called by muse, mutect2, varscan2
- ERICH6 | c.555G>A p.R185= | Splice Region (SNP) | VAF 30/75 reads (40%) | catalogued as COSV55799062; called by muse, mutect2, varscan2
- ERN1 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.351); catalogued as rs1434819919, COSV70500611; called by muse, mutect2, varscan2
- ERVW-1 | c.1127C>A p.A376E | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101423827; called by muse, varscan2
- ESM1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV67318342; called by muse, mutect2, varscan2
- EYA4 | c.1439G>A p.G480E (on ENST00000531901 / NM_001301013.1; = p.G474E on NM_004100.5) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62046681; called by muse, mutect2, varscan2
- EZH1 | c.1096C>T p.H366Y | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.102); catalogued as COSV70548782; called by muse, varscan2
- F5 | c.3089G>A p.R1030Q | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758795781, COSV63121240; ClinVar: uncertain significance; called by mutect2, varscan2
- FAM135B | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52708456; called by muse, mutect2, varscan2
- FAM135B | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199787210; called by mutect2, varscan2
- FAM20A | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV56835797; called by muse, mutect2, varscan2
- FAM3B | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as rs146229700, COSV100783727; called by muse, mutect2, varscan2
- FAM47A | c.1893T>A p.F631L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as COSV60494358; called by mutect2, varscan2
- FAM53A | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778688613, COSV57400529, COSV57403802; called by muse, mutect2, varscan2
- FAT2 | c.12917G>A p.G4306E | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV55814532; called by muse, mutect2, varscan2
- FBXL19 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs771051806, COSV57941046; called by mutect2, varscan2
- FBXO43 | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71053436; called by muse, mutect2, varscan2
- FER | c.2410C>T p.R804C | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777925363, COSV55284265; called by muse, mutect2, varscan2
- FGFR3 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 60/99 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV53393508; called by muse, mutect2, varscan2
- FHL1 | c.156+1G>A p.X52_splice | Splice Site (SNP) | VAF 46/125 reads (37%) | catalogued as COSV61779916; called by muse, mutect2, varscan2
- FIG4 | c.2140A>C p.T714P | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as COSV57785456; called by muse, mutect2, varscan2
- FLACC1 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV53782229; called by muse, mutect2, varscan2
- FMN2 | c.1963A>T p.K655* | Nonsense Mutation (SNP) | VAF 18/96 reads (19%) | catalogued as COSV104409213, COSV60419343; called by mutect2, varscan2
- FMNL2 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56490889; called by muse, mutect2, varscan2
- FMNL2 | c.1565C>T p.S522F | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.082); catalogued as COSV56490899; called by muse, mutect2, varscan2
- FOXA1 | c.404A>G p.N135S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs1321734147, COSV51644159; called by muse, mutect2
- FOXJ1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as COSV53942297; called by muse, mutect2, varscan2
- FOXN1 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV56881814; called by muse, mutect2, varscan2
- FOXN1 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV99881176; called by muse, mutect2, varscan2
- FOXN3 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as COSV54304709; called by muse, mutect2, varscan2
- FSIP2 | c.19657A>G p.K6553E | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.396); catalogued as COSV58079535; called by muse, mutect2, varscan2
- FTHL17 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 26/64 reads (41%) | catalogued as COSV63266486; called by muse, mutect2, varscan2
- FYB2 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 94/292 reads (32%) | catalogued as COSV58583196; called by muse, mutect2, varscan2
- GAB3 | c.1599T>A p.Y533* | Nonsense Mutation (SNP) | VAF 77/220 reads (35%) | catalogued as COSV65818887; called by muse, mutect2, varscan2
- GABRB2 | c.1499C>T p.S500F (on ENST00000274547; = p.S462F on NM_000813.3) | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.995); catalogued as COSV50903913; called by muse, mutect2, varscan2
- GABRG2 | c.989C>T p.S330F (on ENST00000361925 / NM_001375343.1; = p.S290F on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62715259; called by muse, mutect2, varscan2
- GABRG2 | c.1249G>A p.A417T (on ENST00000361925 / NM_001375343.1; = p.A377T on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.562); catalogued as COSV62715802; called by muse, mutect2, varscan2
- GAR1 | c.578T>A p.F193Y | Missense Mutation (SNP) | VAF 79/118 reads (67%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.95); catalogued as COSV56993030; called by mutect2, varscan2
- GBE1 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV70097264; called by mutect2, varscan2
- GCM1 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99452302; called by muse, mutect2, varscan2
- GCSAML | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV63577189; called by muse, mutect2, varscan2
- GFRAL | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.936); catalogued as rs1562053089, COSV61229102; called by muse, mutect2, varscan2
- GFRAL | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as COSV61229110, COSV61233773; called by muse, mutect2, varscan2
- GJA8 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM093956, COSV53787938; called by muse, mutect2, varscan2
- GLDN | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as rs750373261, COSV100118139, COSV59089020; called by muse, mutect2, varscan2
- GLP1R | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV64714395; called by muse, mutect2, varscan2
- GLYATL2 | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV54849167; called by muse, mutect2, varscan2
- GMIP | c.2384C>T p.S795F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV52554549; called by muse, mutect2, varscan2
- GNAS | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.376); catalogued as rs752182669, COSV58328853; called by muse, mutect2, varscan2
- GPR149 | c.1489G>A p.G497R | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs960683593, COSV67666028; called by muse, mutect2, varscan2
- GPR176 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV54443745; called by muse, mutect2, varscan2
- GPR32 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.86); PolyPhen benign (0.173); catalogued as COSV54513827; called by muse, mutect2, varscan2
- GPRASP1 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV64354935; called by muse, mutect2, varscan2
- GPRC6A | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV59951815; called by muse, mutect2, varscan2
- GPRC6A | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV59951823; called by muse, mutect2, varscan2
- GRIK1 | c.1958G>A p.G653E | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765155699, COSV58711884; called by muse, mutect2, varscan2
- GRIN2A | c.4069C>T p.L1357F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58022666; called by muse, mutect2, varscan2
- GRIN2A | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV58022677, COSV58055537; called by muse, mutect2, varscan2
- GRK3 | c.1978C>T p.R660C | Missense Mutation (SNP) | VAF 62/72 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); catalogued as rs1005491210, COSV60793935; called by muse, mutect2, varscan2
- GRSF1 | c.1238A>G p.N413S | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.97); PolyPhen benign (0.089); catalogued as rs781751506, COSV54654726; called by muse, mutect2, varscan2
- GTF3C5 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376483496, COSV59599028, COSV59600639; called by muse, mutect2, varscan2
- GUCY1A1 | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs989003819, COSV56649597; called by muse, mutect2, varscan2
- H1-6 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs760032000, COSV58090053; called by muse, mutect2, varscan2
- H2BC18 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.489); catalogued as COSV58943779; called by muse, mutect2, varscan2
- HAND1 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV50562317; called by mutect2, varscan2
- HARS2 | c.454C>T p.H152Y | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV51226823; called by muse, mutect2, varscan2
- HDAC9 | c.1532G>A p.G511E | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.091); catalogued as COSV67765553, COSV67787311; called by muse, mutect2, varscan2
- HECW2 | c.369G>A p.W123* | Nonsense Mutation (SNP) | VAF 103/263 reads (39%) | catalogued as COSV53651138; called by muse, mutect2, varscan2
- HEXB | c.506T>A p.L169* | Nonsense Mutation (SNP) | VAF 32/68 reads (47%) | catalogued as COSV54666998; called by mutect2, varscan2
- HEXD | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV60063016; called by muse, mutect2, varscan2
- HEY2 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1323370574, COSV64239423; called by mutect2, varscan2
- HEYL | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65721385; called by muse, mutect2, varscan2
- HIF1A | c.1483C>A p.Q495K | Missense Mutation (SNP) | VAF 95/267 reads (36%) | SIFT tolerated (0.98); PolyPhen benign (0.148); catalogued as COSV60188373; called by muse, varscan2
- HIVEP3 | c.4553C>T p.P1518L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV56010530; called by muse, varscan2
- HMGXB4 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 126/164 reads (77%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs560951498, COSV53333069; called by muse, mutect2, varscan2
- HOXB1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV53316540; called by muse, varscan2
- HOXB8 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.679); catalogued as COSV53309952; called by muse, mutect2, varscan2
- HR | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57192741; called by muse, mutect2, varscan2
- HR | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs774329316, COSV57194500; called by muse, mutect2, varscan2
- HTR3B | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs1565555702, COSV52742930; called by muse, mutect2, varscan2
- HTR5A | c.957G>A p.W319* | Nonsense Mutation (SNP) | VAF 104/189 reads (55%) | catalogued as COSV55280931; called by muse, mutect2, varscan2
- HUWE1 | c.10040T>A p.F3347Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.878); catalogued as COSV53336354; called by mutect2, varscan2
- IFT88 | c.1819C>T p.R607C (on ENST00000319980 / NM_001318493.2; = p.R598C on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs369672253; called by muse, mutect2, varscan2
- IGF2BP3 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV51680719; called by muse, varscan2
- IGHJ6 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 14/59 reads (24%) | PolyPhen probably damaging (0.996); catalogued as rs782627627; called by muse, mutect2, varscan2
- IGSF1 | c.407T>A p.I136N | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63836404; called by muse, mutect2, varscan2
- IKBKB | c.1239C>T p.I413= | Splice Region (SNP) | VAF 19/66 reads (29%) | catalogued as COSV60596031; called by muse, mutect2, varscan2
- IL13RA2 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as rs868926440, COSV54564155; called by muse, varscan2
- IL22RA1 | c.1685T>A p.L562H | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV54627675; called by mutect2, varscan2
- IL3RA | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.266); catalogued as COSV58430086; called by muse, mutect2, varscan2
- ILDR1 | c.1193C>T p.S398L (on ENST00000344209 / NM_001199799.2; = p.S354L on NM_175924.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs369610198; called by mutect2, varscan2
- IQGAP1 | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51582051; called by muse, mutect2, varscan2
- IQGAP2 | c.4489G>A p.D1497N | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as COSV57168826; called by muse, mutect2, varscan2
- IRAK1 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV64110115; called by muse, mutect2, varscan2
- ITFG2 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as COSV57389154; called by muse, mutect2, varscan2
- ITGAD | c.1797G>A p.M599I | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs778676347, COSV66756947; called by muse, varscan2
- ITIH2 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as rs757737026, COSV64432154, COSV64432309; called by muse, mutect2, varscan2
- ITPR2 | c.4639C>T p.R1547C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs773730966, COSV67264269; called by mutect2, varscan2
- JAKMIP2 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 141/404 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV54598580; called by muse, mutect2, varscan2
- KANSL3 | c.915C>T p.V305= | Splice Region (SNP) | VAF 28/76 reads (37%) | catalogued as COSV62615894; called by mutect2, varscan2
- KAT6A | c.4364C>T p.T1455I | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1166512057, COSV55903404; called by muse, mutect2, varscan2
- KBTBD6 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV65270963; called by muse, mutect2, varscan2
- KCNH7 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59787670; called by muse, mutect2, varscan2
- KIAA1217 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV56812556, COSV56822769; called by muse, mutect2, varscan2
- KIAA1328 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs536436186, COSV54448669; called by mutect2, varscan2
- KIF13B | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs771289632, COSV73054177; called by muse, mutect2, varscan2
- KIF21A | c.2314C>T p.R772C (on ENST00000361418 / NM_001378440.1; = p.R759C on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs778271459, COSV62768010; called by muse, mutect2, varscan2
- KIN | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as COSV65430043; called by muse, mutect2, varscan2
- KLHL38 | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV58086254; called by muse, mutect2, varscan2
- KLK3 | c.35T>G p.V12G | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV58099025; called by muse, mutect2, varscan2
- KLRC1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.266); catalogued as rs777839485, COSV61724860; called by mutect2, varscan2
- KLRC3 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs138941727, COSV67249991; called by mutect2, varscan2
- KMT2A | c.9284C>T p.P3095L | Missense Mutation (SNP) | VAF 52/79 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as rs1555047613, COSV63282744; called by muse, mutect2, varscan2
- KPNB1 | c.1687C>T p.Q563* | Nonsense Mutation (SNP) | VAF 40/102 reads (39%) | catalogued as COSV51595286; called by muse, mutect2, varscan2
- KRT15 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV54178203; called by muse, mutect2, varscan2
- KRT76 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV60119377; called by muse, mutect2, varscan2
- KRT85 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV57736429; called by mutect2, varscan2
- KRTAP10-9 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1555934766, COSV59953795; called by muse, mutect2, varscan2
- LAMA2 | c.3425G>A p.G1142D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70340072; called by muse, mutect2, varscan2
- LAMA3 | c.8082G>A p.W2694* (on ENST00000313654 / NM_198129.4; = p.W1085* on NM_000227.6) | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as COSV52530638; called by muse, mutect2, varscan2
- LARP1 | c.2866C>T p.R956* (on ENST00000518297 / NM_033551.3; = p.R879* on NM_015315.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as COSV60425149; called by muse, mutect2, varscan2
- LGALS9B | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60864449; called by muse, mutect2, varscan2
- LILRA1 | c.1145T>G p.F382C | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52178609; called by muse, mutect2, varscan2
- LILRB1 | c.293G>A p.R98K (on ENST00000427581; = p.R62K on NM_006669.6) | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV61116334; called by muse, mutect2, varscan2
- LIPF | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as COSV53282756; called by muse, mutect2, varscan2
- LMOD2 | c.622A>T p.S208C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as COSV71755557; called by mutect2, varscan2
- LMX1A | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54217594, COSV99671818; called by muse, mutect2, varscan2
- LPAR4 | c.803T>C p.V268A | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.08); catalogued as COSV70912279, COSV70912438; called by muse, mutect2, varscan2
- LPCAT2 | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50894297; called by muse, mutect2, varscan2
- LRFN2 | c.404A>T p.Q135L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57824360; called by muse, mutect2, varscan2
- LRGUK | c.2248C>T p.P750S | Missense Mutation (SNP) | VAF 70/133 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0.054); catalogued as COSV53634676; called by muse, mutect2, varscan2
- LRRC28 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 72/156 reads (46%) | catalogued as rs778658681, COSV57335921; called by mutect2, varscan2
- LRRC43 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60288281; called by mutect2, varscan2
- LRRC4B | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV65349243; called by muse, mutect2, varscan2
- LVRN | c.1784T>C p.L595P | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.714); catalogued as COSV63496351; called by muse, varscan2
- LYPD1 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs908505086, COSV61415854; called by muse, mutect2, varscan2
- MAEL | c.1064G>A p.G355E | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.154); catalogued as COSV63304052; called by muse, mutect2, varscan2
- MAGEA10 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 80/285 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV54883044; called by muse, mutect2, varscan2
- MAGEB6 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as COSV66871956; called by muse, mutect2, varscan2
- MAML3 | c.2182G>A p.G728S | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs143572204; called by muse, varscan2
- MAN1A1 | c.898-1G>A p.X300_splice | Splice Site (SNP) | VAF 17/36 reads (47%) | catalogued as COSV63781388; called by muse, mutect2, varscan2
- MAOB | c.429G>A p.W143* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV65204421; called by muse, mutect2, varscan2
- MAP10 | c.1928A>G p.N643S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV69362903; called by muse, mutect2, varscan2
- MAP3K19 | c.2872G>A p.D958N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV59636981; called by muse, mutect2, varscan2
- MAP3K19 | c.2169G>A p.M723I | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1455242886, COSV59636990; called by muse, mutect2, varscan2
- MAP3K19 | c.24A>C p.E8D | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.017); catalogued as COSV59637002; called by muse, mutect2, varscan2
- MAP3K21 | c.1904C>T p.S635L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV64041137; called by muse, mutect2, varscan2
- MAP3K21 | c.2603C>T p.S868F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV64041146; called by muse, varscan2
- MAP7D1 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV60214819; called by muse, mutect2, varscan2
- MARF1 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60020446; called by muse, varscan2
- MATN3 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs561790770, COSV68099444; called by muse, mutect2, varscan2
- MCCD1 | c.171G>A p.R57= | Splice Region (SNP) | VAF 12/45 reads (27%) | catalogued as COSV66018709; called by muse, mutect2, varscan2
- MCF2 | c.2504C>T p.S835F | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV58479036; called by muse, mutect2, varscan2
- MCL1 | c.647T>G p.V216G | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100329517; called by muse, mutect2, varscan2
- MCTP2 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.16); catalogued as COSV100752054; called by mutect2, varscan2
- MCU | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV64064851; called by muse, mutect2, varscan2
- MDN1 | c.13861G>A p.V4621I | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs779947398, COSV65518014; called by muse, mutect2, varscan2
- MDN1 | c.12571G>A p.G4191R | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65518019; called by muse, mutect2, varscan2
- MED12L | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56370234, COSV99851498; called by muse, mutect2, varscan2
- MFAP5 | c.140-1G>T p.X47_splice | Splice Site (SNP) | VAF 14/48 reads (29%) | catalogued as COSV63945123; called by mutect2, varscan2
- MGAT5B | c.1886G>A p.G629E (on ENST00000569840 / NM_001199172.2; = p.G627E on NM_144677.3) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56926044; called by muse, mutect2
- MIB2 | c.2968C>T p.R990C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as rs1316459294, COSV61542431; called by mutect2, varscan2
- MINAR1 | c.2486C>T p.S829F | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV59581153; called by muse, mutect2, varscan2
- MLXIPL | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57667067; called by muse, varscan2
- MME | c.2216C>T p.S739L | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV64706184; called by muse, mutect2, varscan2
- MORC4 | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV55239939; called by muse, mutect2, varscan2
- MROH2B | c.2500C>T p.R834W | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs368507319; called by muse, mutect2, varscan2
- MROH2B | c.2180C>T p.S727F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV68181692; called by muse, mutect2, varscan2
- MROH2B | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68188956; called by muse, mutect2, varscan2
- MROH2B | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV68181244; called by muse, mutect2, varscan2
- MRPL30 | c.416T>A p.L139H | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV57666600; called by mutect2, varscan2
- MSLN | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.812); catalogued as rs749200543, COSV53503642; called by mutect2, varscan2
- MTR | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 149/287 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63967180; called by muse, mutect2, varscan2
- MUC16 | c.35687C>T p.S11896F | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.319); catalogued as rs1568727347, COSV67448653; called by muse, varscan2
- MUC16 | c.35569G>A p.E11857K | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV67448660; called by muse, varscan2
- MUC16 | c.35377C>T p.P11793S | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.584); catalogued as COSV67448668; called by muse, mutect2, varscan2
- MUC16 | c.23596G>A p.E7866K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as rs768701273, COSV67448689; called by muse, mutect2, varscan2
- MUC16 | c.14744T>C p.V4915A | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as rs1368913332, COSV67448704; called by muse, mutect2, varscan2
- MUC16 | c.9977G>A p.G3326E | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.948); catalogued as COSV67448715; called by muse, mutect2, varscan2
- MUC16 | c.8788T>A p.S2930T | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV67448721; called by muse, mutect2, varscan2
- MXRA5 | c.5203A>T p.N1735Y | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54225551; called by muse, mutect2, varscan2
- MXRA5 | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV54225575; called by muse, mutect2, varscan2
- MXRA5 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866233220, COSV54222468; called by muse, varscan2
- MYLK3 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67362739; called by muse, mutect2, varscan2
- MYO15A | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.085); catalogued as rs962349967, COSV99232240; called by muse, mutect2, varscan2
- MYO15A | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99232242; called by muse, mutect2, varscan2
- MYO1G | c.2288G>A p.R763K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs1181665721, COSV51853318, COSV99348541; called by muse, mutect2, varscan2
- MYO7B | c.2993T>C p.L998S | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67345031; called by muse, varscan2
- MYOT | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); catalogued as rs766736443, COSV51795048; called by muse, varscan2
- N4BP2 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1194614436, COSV54699625, COSV54702803; called by muse, mutect2, varscan2
- NAA11 | c.497A>G p.K166R | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV54513985; called by muse, varscan2
- NAV2 | c.1699C>T p.P567S (on ENST00000396087 / NM_001244963.2; = p.P544S on NM_145117.5) | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62316487; called by muse, mutect2, varscan2
- NAV3 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV57064769; called by muse, mutect2, varscan2
- NAV3 | c.4920G>T p.Q1640H | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57064804; called by mutect2, varscan2
- NDRG4 | c.311G>A p.G104E (on ENST00000570248 / NM_001378344.1; = p.G136E on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV50746611; called by muse, mutect2, varscan2
- NDUFAF4 | c.386del p.F129Sfs*10 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as COSV100293992; called by pindel, varscan2
- NEK7 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV66314126; called by muse, mutect2, varscan2
- NETO2 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 33/84 reads (39%) | catalogued as rs144229750, COSV57451601; called by muse, mutect2, varscan2
- NFASC | c.1721A>T p.D574V (on ENST00000339876 / NM_001378329.1; = p.D585V on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV58360201; called by muse, mutect2, varscan2
- NFKBIZ | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.922); catalogued as rs200547087, COSV58199597; called by muse, mutect2, varscan2
- NGLY1 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775963261, COSV54984351; called by muse, mutect2, varscan2
- NHS | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV66271997; called by mutect2, varscan2
- NLGN1 | c.2284T>A p.Y762N | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64324814; called by mutect2, varscan2
- NLRP12 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV60744112; called by muse, mutect2, varscan2
- NLRP13 | c.2317G>A p.D773N | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.042); catalogued as COSV61620306; called by muse, mutect2, varscan2
- NLRP9 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 212/569 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.223); catalogued as COSV60460416; called by muse, varscan2
- NMBR | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57800516; called by muse, mutect2, varscan2
- NMNAT3 | c.151G>A p.D51N (on ENST00000296202 / NM_001320512.1; = p.D14N on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1376883874, COSV56155126; called by muse, mutect2, varscan2
- NOS1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.89); PolyPhen benign (0.018); catalogued as COSV57607786; called by muse, mutect2, varscan2
- NOS3 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.314); catalogued as COSV52486851; called by muse, mutect2, varscan2
- NOTCH2 | c.4001C>T p.P1334L | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as rs772588398, COSV56683504; called by muse, mutect2, varscan2
- NPY1R | c.347A>T p.N116I | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV56713457; called by muse, mutect2
- NPY1R | c.345G>T p.L115F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV56713469; called by muse, mutect2
- NR2F6 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs757103571, COSV52242923, COSV52245258; called by muse, mutect2, varscan2
- NRK | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1450758963, COSV54591059; called by mutect2, varscan2
- NUDT7 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV51744609; called by muse, varscan2
- NUP43 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV61188966; called by muse, mutect2, varscan2
- NUP93 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV57429020; called by muse, mutect2, varscan2
- OGT | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as COSV65479723; called by mutect2, varscan2
- OLFML2B | c.1735C>T p.R579C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54194598; called by muse, mutect2, varscan2
- OPN5 | c.206A>C p.E69A | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55244418; called by muse, mutect2, varscan2
- OR10H2 | c.571A>T p.N191Y | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV59945459; called by mutect2, varscan2
- OR10P1 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs752834026, COSV59007072; called by mutect2, varscan2
- OR13C2 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV73377659; called by muse, mutect2, varscan2
- OR2A1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs560002930, COSV101283374; called by mutect2, varscan2
- OR2G2 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs535355641, COSV60739578; called by muse, varscan2
- OR2G2 | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as COSV60739583; called by muse, varscan2
- OR2M3 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV71758895; called by muse, mutect2, varscan2
- OR2T3 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 36/358 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs552029313, COSV100613474, COSV62081866; called by mutect2, varscan2
- OR2T4 | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 69/316 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV100822402, COSV63543440; called by muse, mutect2, varscan2
- OR4D5 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 71/124 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs138187932; called by muse, mutect2, varscan2
- OR51A2 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 59/87 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV66748122; called by muse, mutect2, varscan2
- OR51L1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs1212251668, COSV58624046; called by muse, mutect2, varscan2
- OR52B2 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73209240; called by muse, mutect2, varscan2
- OR5B12 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV56904136; called by muse, mutect2, varscan2
- OR5H14 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV101454343, COSV71193561; called by muse, mutect2, varscan2
- OR7G3 | c.678G>A p.M226I | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV59639854; called by muse, mutect2, varscan2
- OR8B2 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV66664340; called by muse, mutect2, varscan2
- OR9I1 | c.644T>C p.L215P | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56925451; called by muse, mutect2, varscan2
- OSBPL7 | c.2393A>G p.N798S | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV50107019; called by muse, mutect2, varscan2
- PAAF1 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.606); catalogued as COSV60154660; called by muse, mutect2, varscan2
- PACSIN1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.373); catalogued as rs868122304, COSV55058818; called by muse, mutect2, varscan2
- PAN2 | c.2755C>T p.L919F (on ENST00000425394 / NM_001127460.3; = p.L915F on NM_014871.5) | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV57752937; called by muse, mutect2, varscan2
- PAPLN | c.1157C>T p.S386F (on ENST00000554301; = p.S359F on NM_173462.4) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs763130733, COSV53714111; called by muse, mutect2, varscan2
- PAPPA2 | c.2915C>T p.S972F | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV62791796; called by muse, mutect2, varscan2
- PCDH1 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as COSV99745959; called by muse, mutect2, varscan2
- PCDH11X | c.55T>C p.F19L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.011); catalogued as COSV53446714; called by muse, mutect2, varscan2
- PCDHA10 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.104); catalogued as COSV56481271; called by muse, mutect2, varscan2
- PCDHA6 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.909); catalogued as COSV65342295; called by mutect2, varscan2
- PCDHB1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as rs1254111938, COSV60629676; called by muse, mutect2, varscan2
- PCDHB5 | c.2243A>T p.Y748F | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50647732, COSV50659815; called by muse, mutect2, varscan2
- PCDHB7 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs782446116, COSV50755429; called by muse, mutect2, varscan2
- PCDHB7 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50755464; called by muse, mutect2, varscan2
- PCDHGA12 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.191); catalogued as COSV52745065; called by muse, mutect2, varscan2
- PCDHGB3 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 93/269 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.166); catalogued as rs1393089776, COSV53907465; called by muse, mutect2, varscan2
- PCDHGB4 | c.2362C>T p.P788S | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as rs1401463493, COSV53907485; called by muse, mutect2, varscan2
- PCLO | c.13807G>A p.E4603K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV61618780; called by muse, mutect2, varscan2
- PCLO | c.12397C>T p.R4133C | Missense Mutation (SNP) | VAF 62/114 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372497499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCLO | c.5299T>G p.L1767V | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61618802; called by muse, mutect2, varscan2
- PDE1B | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as rs137936270; called by muse, mutect2, varscan2
- PDIA3 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs1486306246, COSV55854916; called by muse, mutect2, varscan2
- PDZRN4 | c.3006A>T p.K1002N (on ENST00000402685 / NM_001164595.2; = p.K744N on NM_013377.4) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54193693, COSV54217784; called by mutect2, varscan2
- PEG3 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.554); catalogued as rs761429479, COSV55626627; called by muse, mutect2, varscan2
- PFAS | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58978736; called by muse, mutect2, varscan2
- PHF7 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.383); catalogued as rs867468196, COSV59978787; called by muse, mutect2, varscan2
- PHKA1 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV59802355; called by mutect2, varscan2
- PHYH | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs947056017, COSV53814877; called by muse, mutect2, varscan2
- PID1 | c.725C>T p.S242F (on ENST00000354069 / NM_001330156.1; = p.S240F on NM_017933.5) | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV62472576; called by muse, mutect2, varscan2
- PID1 | c.649G>A p.E217K (on ENST00000354069 / NM_001330156.1; = p.E215K on NM_017933.5) | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV62473102; called by muse, mutect2, varscan2
- PIGO | c.2360C>T p.P787L | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.56); PolyPhen benign (0.418); catalogued as rs1396329353, COSV53052629; called by muse, mutect2, varscan2
- PKD1L1 | c.4789G>A p.E1597K | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV56959070; called by muse, mutect2, varscan2
- PKHD1L1 | c.6542C>T p.S2181F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65738443; called by muse, mutect2, varscan2
- PKN1 | c.1744C>T p.Q582* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99466389; called by muse, mutect2, varscan2
- PKP4 | c.2624C>T p.P875L | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382553864, COSV61578037; called by muse, mutect2, varscan2
- PLA2G4D | c.1637G>A p.G546E | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51819421; called by muse, mutect2, varscan2
- PLA2G4E | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs567649717, COSV68149047, COSV68149931; called by mutect2, varscan2
- PLD1 | c.2767C>T p.R923C | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs528205914, COSV60565869; called by mutect2, varscan2
- PLEC | c.4216C>T p.Q1406* (on ENST00000322810 / NM_201380.4; = p.Q1296* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 41/132 reads (31%) | catalogued as COSV59608281; called by muse, mutect2, varscan2
- PLEKHA6 | c.2779C>T p.P927S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV55330638; called by muse, mutect2, varscan2
- PLG | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV51981110; called by muse, mutect2, varscan2
- PLLP | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV54657740; called by muse, mutect2, varscan2
- PLPP2 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749465260, COSV54119764; called by muse, varscan2
- PLXDC2 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 27/41 reads (66%) | catalogued as COSV65901241; called by muse, mutect2, varscan2
- PNLDC1 | c.1243T>A p.Y415N | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV51704042; called by muse, mutect2, varscan2
- POLE | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs878854844, COSV57675102; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POM121 | c.3007C>T p.P1003S (on ENST00000434423; = p.P738S on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV57511485, COSV57516975; called by muse, varscan2
- POPDC2 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs377607045, COSV51739912; called by muse, mutect2, varscan2
- POSTN | c.2258G>A p.R753Q | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.14); catalogued as rs973689907, COSV65712042; called by muse, mutect2, varscan2
- PPP1R3C | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 35/50 reads (70%) | catalogued as rs747930364, COSV53287774; called by muse, varscan2
- PPP3CA | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV59920194, COSV59929117; called by muse, mutect2, varscan2
- PRAMEF17 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs989031993; called by muse, mutect2, varscan2
- PRDM16 | c.2727G>C p.E909D | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV54580528; called by muse, mutect2, varscan2
- PRICKLE3 | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66234072; called by mutect2, varscan2
- PRKCB | c.1336T>C p.Y446H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57768418; called by muse, mutect2, varscan2
- PRKG2 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 131/243 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs867660938, COSV52320273; called by muse, mutect2, varscan2
- PRPS1L1 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 204/386 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs1163485317, COSV72649828; called by muse, varscan2
- PRSS1 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as CM011002, COSV61190935; called by muse, mutect2, varscan2
- PRSS54 | c.507G>A p.W169* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as COSV54685224; called by muse, mutect2, varscan2
- PSG11 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 95/285 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60453870; called by mutect2, varscan2
- PSG3 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.613); catalogued as COSV100548872; called by muse, mutect2, varscan2
- PTCH1 | c.2072C>T p.T691I | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV59464778; called by muse, mutect2, varscan2
- PTGIR | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as COSV52191493; called by muse, mutect2, varscan2
- PTPN13 | c.6637C>T p.P2213S (on ENST00000411767 / NM_080683.3; = p.P2194S on NM_006264.3) | Missense Mutation (SNP) | VAF 52/78 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750632263, COSV57403374, COSV57406786; called by muse, varscan2
- PTPN6 | c.1429G>A p.G477S | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59683558; called by muse, mutect2, varscan2
- PTPN7 | c.835G>A p.E279K (on ENST00000495688; = p.E318K on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV100460216, COSV58311765; called by muse, mutect2, varscan2
- PTPRB | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.26); catalogued as COSV54234127; called by muse, mutect2, varscan2
- PTPRF | c.4204G>A p.G1402R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202116615, COSV100740799; called by mutect2, varscan2
- PTPRF | c.4205G>A p.G1402E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100740800; called by muse, mutect2, varscan2
- PTPRK | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV63892014; called by muse, mutect2, varscan2
- PTPRT | c.2674G>A p.E892K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs724159843, COSV61963674; called by muse, mutect2, varscan2
- PUM2 | c.2644C>T p.P882S | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.239); catalogued as COSV57578302; called by muse, mutect2, varscan2
- QKI | c.848T>A p.L283* | Nonsense Mutation (SNP) | VAF 32/69 reads (46%) | catalogued as COSV51689979; called by muse, mutect2, varscan2
- QSER1 | c.4934C>T p.T1645I (on ENST00000399302; = p.T1774I on NM_001076786.3) | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67899679; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2972C>T p.A991V | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs377291864; called by muse, mutect2, varscan2
- RABEP1 | c.65A>T p.E22V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52583031; called by muse, mutect2, varscan2
- RABGEF1 | c.1186C>A p.R396S (on ENST00000439720 / NM_001287061.2; = p.R383S on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as COSV53160976, COSV99534784; called by muse, varscan2
- RANBP17 | c.2470C>T p.P824S | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV66645238; called by muse, mutect2, varscan2
- RASEF | c.515A>G p.N172S | Missense Mutation (SNP) | VAF 63/106 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.134); catalogued as COSV64586065; called by muse, mutect2, varscan2
- RBL1 | c.1876C>T p.R626* | Nonsense Mutation (SNP) | VAF 45/118 reads (38%) | catalogued as rs778997257, COSV60328604; called by muse, mutect2, varscan2
- RBM22 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); catalogued as COSV52270618, COSV99556116; called by muse, mutect2, varscan2
- RCOR1 | c.1063A>G p.I355V | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs565329339, COSV51766088; called by muse, mutect2, varscan2
- RELB | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.807); catalogued as COSV55508559; called by muse, mutect2, varscan2
- RELCH | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs1481858751, COSV56882713; called by muse, mutect2, varscan2
- RELN | c.2162C>T p.S721F | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV58988076; called by muse, varscan2
- RFPL2 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV50709033; called by muse, mutect2, varscan2
- RFTN1 | c.827-1G>A p.X276_splice | Splice Site (SNP) | VAF 79/131 reads (60%) | catalogued as rs1444388556, COSV61917131; called by muse, mutect2, varscan2
- RFX4 | c.1586C>T p.S529F (on ENST00000392842 / NM_213594.3; = p.S435F on NM_032491.6) | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.962); catalogued as COSV57572856; called by muse, mutect2, varscan2
- RHOB | c.188A>C p.Q63P | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55355514; called by muse, mutect2, varscan2
- RINL | c.451G>A p.D151N (on ENST00000591812 / NM_001195833.2; = p.D37N on NM_198445.4) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as rs755164424, COSV61574077; called by muse, mutect2, varscan2
- RNF180 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs771469217, COSV56960067; called by mutect2, varscan2
- RNF213 | c.1727G>T p.W576L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60619626; called by muse, mutect2, varscan2
- ROR2 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV65216886; called by muse, mutect2, varscan2
- RPH3A | c.1670C>T p.S557F (on ENST00000389385 / NM_001143854.2; = p.S553F on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66990145; called by muse, mutect2, varscan2
- RPH3AL | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs568520768, COSV58738731; called by mutect2, varscan2
- RPL5 | c.7T>C p.F3L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV59872919; called by muse, mutect2, varscan2
- RPS16 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV52238770; called by muse, mutect2, varscan2
- RPTN | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as COSV60166496; called by muse, varscan2
- RPTN | c.139-2A>C p.X47_splice | Splice Site (SNP) | VAF 35/67 reads (52%) | catalogued as COSV100285430; called by muse, varscan2
- RTL3 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as rs1450495384, COSV58183355; called by muse, mutect2, varscan2
- RXFP2 | c.1494G>A p.M498I | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV53633477; called by muse, mutect2, varscan2
- RYK | c.898G>A p.G300S (on ENST00000620660 / NM_001005861.2; = p.X297_splice on NM_002958.4) | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56060979; called by muse, mutect2, varscan2
- RYR1 | c.4270G>A p.E1424K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as rs543630280, COSV62090739; ClinVar: uncertain significance; called by mutect2, varscan2
- RYR1 | c.9905C>T p.P3302L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.081); catalogued as rs777896104, COSV100615401, COSV62092248, COSV62103390; called by muse, mutect2, varscan2
- RYR3 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.174); catalogued as rs752846417, COSV66779860; ClinVar: uncertain significance; called by mutect2, varscan2
- RYR3 | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66779865; called by muse, mutect2, varscan2
- S100A7L2 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.471); catalogued as rs761029465, COSV64194825; called by muse, mutect2, varscan2
- SALL1 | c.362G>A p.R121K | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51754011; called by muse, mutect2, varscan2
- SALL3 | c.2653G>A p.D885N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776838246, COSV73305812; called by mutect2, varscan2
- SATL1 | c.1229G>A p.G410E (on ENST00000395409; = p.G597E on NM_001012980.2) | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60575596; called by muse, mutect2, varscan2
- SCN1A | c.4177C>T p.H1393Y (on ENST00000303395 / NM_001202435.3; = p.H1382Y on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57662186; called by mutect2, varscan2
- SCN9A | c.3103G>A p.E1035K (on ENST00000303354; = p.E1024K on NM_002977.3) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV57601937; called by muse, mutect2, varscan2
- SCN9A | c.508A>T p.K170* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as rs1199159235, COSV57601950; called by mutect2, varscan2
- SCNN1A | c.1359G>A p.W453* | Nonsense Mutation (SNP) | VAF 43/110 reads (39%) | catalogued as COSV57434293; called by muse, mutect2, varscan2
- SCP2D1 | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as rs776432081, COSV53856670; called by muse, mutect2, varscan2
- SCUBE3 | c.988C>T p.H330Y | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51455157; called by muse, mutect2, varscan2
- SDR42E1 | c.215A>G p.D72G | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV61093843; called by muse, varscan2
- SEC23A | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV56971406; called by muse, mutect2, varscan2
- SEC24C | c.2092C>T p.L698F | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765109425, COSV59540302; called by muse, mutect2, varscan2
- SELP | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55248900; called by muse, varscan2
- SEMA3F | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs1045993195, COSV50028423; called by muse, mutect2, varscan2
- SEMA4C | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59689805; called by muse, mutect2, varscan2
- SEMA4F | c.1242G>A p.M414I | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs769588310, COSV100335921; called by muse, mutect2, varscan2
- SEMA4F | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV60282127; called by muse, mutect2, varscan2
- SEPTIN1 | c.522G>C p.K174N (on ENST00000321367; = p.K127N on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV58441438; called by muse, mutect2, varscan2
- SEPTIN6 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.988); catalogued as rs767841172, COSV59712779; called by mutect2, varscan2
- SERINC3 | c.1120C>T p.L374F | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV54855585; called by muse, mutect2, varscan2
- SFTPD | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV64852686; called by muse, mutect2, varscan2
- SGSM3 | c.1386T>A p.Y462* | Nonsense Mutation (SNP) | VAF 15/28 reads (54%) | catalogued as COSV50651296; called by muse, mutect2, varscan2
- SH2D4B | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV57893258; called by mutect2, varscan2
- SHD | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV56666161; called by muse, mutect2, varscan2
- SHISAL1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 143/180 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66987502; called by muse, varscan2
- SHOC1 | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as rs1364563073, COSV59498141; called by muse, mutect2
- SHROOM2 | c.3403G>A p.G1135R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV66604985; called by muse, varscan2
- SHROOM4 | c.2681G>A p.G894E | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); catalogued as COSV56785278; called by muse, mutect2, varscan2
- SIDT1 | c.2281T>A p.F761I | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53498779; called by mutect2, varscan2
- SIGLEC10 | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 28/56 reads (50%) | catalogued as COSV59479412; called by muse, mutect2, varscan2
- SIRPB2 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100708385, COSV100708480; called by muse, mutect2, varscan2
- SLC12A8 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV58863488; called by muse, mutect2, varscan2
- SLC15A1 | c.1274A>T p.N425I | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as COSV64730238; called by muse, mutect2, varscan2
- SLC15A2 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV55196288; called by muse, mutect2, varscan2
- SLC22A7 | c.691G>A p.V231M (on ENST00000372585 / NM_153320.2; = p.V229M on NM_006672.3) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.096); catalogued as rs757209300, COSV65353641; called by mutect2, varscan2
- SLC24A4 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1472393642, COSV54108219; called by muse, mutect2, varscan2
- SLC25A31 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs267600020, COSV55418138; called by muse, mutect2, varscan2
- SLC26A9 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61601105; called by muse, mutect2, varscan2
- SLC32A1 | c.886A>G p.K296E | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.115); catalogued as COSV54145846; called by muse, mutect2, varscan2
- SLC34A3 | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100746648; called by muse, mutect2, varscan2
- SLC4A8 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 28/61 reads (46%) | catalogued as COSV60648410; called by muse, mutect2, varscan2
- SLC7A3 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV53226750; called by muse, mutect2, varscan2
- SLC7A8 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57553177; called by muse, mutect2, varscan2
- SLC7A8 | c.304A>G p.K102E | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV57553185; called by muse, mutect2, varscan2
- SLC9A7 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); catalogued as rs745454488, COSV60378187; called by muse, mutect2, varscan2
- SLC9A9 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV57219683; called by muse, mutect2, varscan2
- SLC9C1 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV59885674; called by muse, mutect2, varscan2
- SMARCC2 | c.1724T>C p.F575S | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57214757; called by muse, mutect2, varscan2
- SMG7 | c.2557C>T p.P853S | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as COSV61629974; called by muse, mutect2, varscan2
- SMPDL3B | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV65870142; called by muse, mutect2, varscan2
- SNAP25 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.367); catalogued as rs866969321, COSV54770798, COSV54771307; called by muse, varscan2
- SOX6 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 72/113 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57038526; called by muse, mutect2, varscan2
- SP7 | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs187209359, COSV58190492; called by muse, mutect2, varscan2
- SPAG17 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); catalogued as COSV60453817; called by muse, mutect2, varscan2
- SPEG | c.6663A>C p.E2221D | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as COSV56664281; called by muse, mutect2, varscan2
- SPEM2 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs751398074, COSV61603256; called by muse, mutect2, varscan2
- SPEN | c.3743C>T p.S1248L | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV65358462; called by muse, mutect2, varscan2
- SPRR3 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs372827652, COSV99768368; called by muse, mutect2, varscan2
- SPTA1 | c.3356A>T p.K1119M | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63749693; called by mutect2, varscan2
- SRCAP | c.8921C>T p.P2974L | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs1260768315, COSV52668299; called by muse, mutect2, varscan2
- SRGAP2 | c.2374G>A p.E792K (on ENST00000624873 / NM_001170637.4; = p.E793K on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as rs1553377784, COSV55333927; called by muse, mutect2, varscan2
- ST8SIA3 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 55/123 reads (45%) | PolyPhen probably damaging (1); catalogued as rs145545626, COSV60653431, COSV60654584; called by muse, mutect2, varscan2
- STAB2 | c.3686T>A p.F1229Y | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV66335191; called by mutect2, varscan2
- STAG2 | c.1631G>A p.G544E | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54352007; called by muse, mutect2, varscan2
- STAMBPL1 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV64228789; called by muse, mutect2, varscan2
- STKLD1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV64311721; called by muse, mutect2, varscan2
- SUGP1 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.115); catalogued as COSV53233844; called by muse, mutect2, varscan2
- SUMO1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV66260054; called by muse, mutect2, varscan2
- SUPT6H | c.2323C>T p.Q775* | Nonsense Mutation (SNP) | VAF 27/76 reads (36%) | catalogued as COSV58925028; called by muse, mutect2, varscan2
- SYCP2 | c.1291G>A p.G431R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs768778759, COSV62766351; called by muse, varscan2
- SYT16 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV70855209, COSV70858311; called by muse, mutect2, varscan2
- SYT2 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV66141320; called by muse, mutect2, varscan2
- SYVN1 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV53694774; called by muse, mutect2, varscan2
- TACC2 | c.2647G>A p.E883K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV57747947; called by muse, mutect2, varscan2
- TAF9B | c.164A>T p.K55I | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59370892; called by muse, mutect2, varscan2
- TAOK3 | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as rs61945215, COSV66824881; called by muse, mutect2, varscan2
- TAS2R8 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as rs768949566, COSV53688045; called by muse, mutect2, varscan2
- TBX20 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV68782776; called by muse, mutect2, varscan2
- TCEAL3 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV54580157; called by muse, mutect2, varscan2
- TCHHL1 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.344); catalogued as COSV64285017; called by muse, mutect2, varscan2
- TDG | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 89/234 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1333646142, COSV57165235; called by muse, mutect2, varscan2
- TDP1 | c.1766T>G p.I589R | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV59642328; called by muse, mutect2, varscan2
- TDP2 | c.667A>G p.M223V | Missense Mutation (SNP) | VAF 125/313 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV61966504; called by muse, mutect2, varscan2
- TDRD5 | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1262356071, COSV54239510; called by mutect2, varscan2
- TEC | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67403655; called by muse, mutect2, varscan2
- TENT4A | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.205); catalogued as COSV50094504; called by muse, mutect2, varscan2
- TEP1 | c.2660C>T p.P887L | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV52988827, COSV99402499; called by muse, mutect2, varscan2
- TEX14 | c.868G>A p.D290N (on ENST00000240361 / NM_001201457.2; = p.D284N on NM_031272.5) | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs140185813, COSV53612647; called by muse, mutect2, varscan2
- TGOLN2 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 95/261 reads (36%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.975); catalogued as COSV56405399; called by muse, mutect2, varscan2
- THSD7B | c.3813G>A p.M1271I (on ENST00000272643; = p.M1269I on NM_001316349.2) | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1401574016, COSV55659689; called by muse, mutect2, varscan2
- TIE1 | c.912A>C p.E304D | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV65248701; called by muse, mutect2, varscan2
- TINF2 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV57468190; called by muse, mutect2, varscan2
- TLN2 | c.5117C>T p.S1706L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.154); catalogued as rs142261304; called by muse, mutect2, varscan2
- TLR9 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV62345729, COSV62348712; called by muse, mutect2, varscan2
- TMC3 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.108); catalogued as COSV63922379; called by muse, mutect2, varscan2
- TMEM100 | c.19A>G p.K7E | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.389); catalogued as rs1567921602, COSV70117920, COSV70118153; called by muse, mutect2, varscan2
- TMEM104 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59108347; called by muse, mutect2, varscan2
- TMEM104 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100120634; called by muse, mutect2, varscan2
- TMEM200A | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as rs267600806; called by mutect2, varscan2
- TMEM26 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.017); catalogued as rs759756456, COSV53261192; called by mutect2, varscan2
- TMEM35A | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV54501010; called by muse, varscan2
- TMPRSS12 | c.841A>G p.R281G | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV101269166, COSV68255860; called by muse, varscan2
- TMTC1 | c.1030C>T p.P344S (on ENST00000539277 / NM_001193451.2; = p.P236S on NM_175861.3) | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1441331543, COSV55476360; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.649T>A p.F217I | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59528195; called by mutect2, varscan2
- TNXB | c.10295C>T p.S3432F (on ENST00000647633; = p.S3185F on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 137/366 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64473861, COSV64474553; called by muse, mutect2, varscan2
- TNXB | c.5819C>T p.S1940F (on ENST00000647633; = p.S1693F on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV64474556; called by muse, mutect2, varscan2
- TNXB | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 98/260 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV64474558; called by muse, mutect2, varscan2
- TPK1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 108/173 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV63637731; called by muse, mutect2, varscan2
- TPTE | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1255945263; called by mutect2, varscan2
- TRAF3IP1 | c.214T>A p.F72I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64852146; called by mutect2, varscan2
- TRANK1 | c.8530G>A p.V2844I | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV57142729; called by muse, mutect2, varscan2
- TRANK1 | c.1855C>T p.H619Y | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.062); catalogued as COSV57142754; called by muse, mutect2, varscan2
- TRIM24 | c.2227G>A p.E743K (on ENST00000343526 / NM_015905.3; = p.E709K on NM_003852.4) | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV58969644; called by muse, mutect2, varscan2
- TRIM54 | c.326A>G p.K109R | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV56082275; called by muse, mutect2, varscan2
- TRMT13 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.294); catalogued as COSV61582731; called by muse, mutect2, varscan2
- TRPM4 | c.668T>G p.F223C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV53260613; called by muse, mutect2, varscan2
- TRPM7 | c.2872T>C p.F958L | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.401); catalogued as rs764487978, COSV57913902; called by muse, mutect2, varscan2
- TSPYL4 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV60306465; called by muse, mutect2, varscan2
- TTBK1 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.315); catalogued as rs780727068, COSV52488660, COSV99035668; called by mutect2, varscan2
- TTC3 | c.3884C>T p.S1295F | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as COSV61286608; called by muse, mutect2, varscan2
- TTLL2 | c.1679T>A p.F560Y | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as COSV53442720; called by mutect2, varscan2
- TTLL7 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751771225, COSV53081912; called by muse, mutect2, varscan2
- TTN | c.100318G>A p.E33440K (on ENST00000591111; = p.E26016K on NM_003319.4) | Missense Mutation (SNP) | VAF 48/114 reads (42%) | PolyPhen possibly damaging (0.778); catalogued as rs779952686, COSV59911590; called by muse, mutect2, varscan2
- TTN | c.24871G>A p.E8291K (on ENST00000591111; = p.E7364K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | PolyPhen possibly damaging (0.788); catalogued as COSV100605131, COSV59911623; called by muse, mutect2, varscan2
- TTN | c.8806C>T p.H2936Y (on ENST00000591111; = p.H2890Y on NM_003319.4) | Missense Mutation (SNP) | VAF 79/250 reads (32%) | PolyPhen probably damaging (0.994); catalogued as COSV59911634, COSV60366513; called by muse, mutect2, varscan2
- TYRO3 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as COSV55481030; called by muse, mutect2, varscan2
- UPF3B | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52229409, COSV99351936; called by muse, mutect2, varscan2
- UPRT | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as COSV64912161; called by muse, mutect2, varscan2
- USH2A | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1423536179, CM044736, COSV56334150; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP16 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.089); catalogued as COSV57624232; called by muse, mutect2, varscan2
- USP29 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV54237548; called by muse, mutect2, varscan2
- USP9X | c.7303C>T p.P2435S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV61066564; called by muse, mutect2, varscan2
- UTP14C | c.2038C>T p.Q680* | Nonsense Mutation (SNP) | VAF 74/190 reads (39%) | catalogued as COSV73000582; called by muse, mutect2, varscan2
- VANGL2 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751810965, COSV63604084, COSV63605123; called by muse, mutect2, varscan2
- VAV1 | c.558G>A p.P186= | Splice Region (SNP) | VAF 4/10 reads (40%) | catalogued as rs1434383608, COSV100408725; called by mutect2, varscan2
- VNN3 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1562230519, COSV99258220; called by muse, mutect2, varscan2
- VPS13C | c.8462C>T p.S2821L (on ENST00000644861 / NM_020821.3; = p.S2778L on NM_017684.5) | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV51126056, COSV51147990; called by muse, mutect2, varscan2
- VPS13C | c.6712C>T p.L2238F (on ENST00000644861 / NM_020821.3; = p.L2195F on NM_017684.5) | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs778347062, COSV51126174, COSV99829229; called by muse, mutect2, varscan2
- WAS | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1440423616, COSV64996636; called by mutect2, varscan2
- WDFY3 | c.1906C>T p.R636* | Nonsense Mutation (SNP) | VAF 14/23 reads (61%) | catalogued as rs764271607, COSV55694618; called by muse, mutect2, varscan2
- WDR6 | c.2390G>A p.G797D | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.888); catalogued as COSV58244094; called by muse, mutect2, varscan2
- WDR74 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV53678163; called by muse, mutect2, varscan2
- WNT7B | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 44/56 reads (79%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.511); catalogued as rs889418995, COSV59748542; called by muse, mutect2, varscan2
- WSCD1 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV58494126; called by mutect2, varscan2
- XIRP1 | c.5273G>A p.S1758N | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV61137244; called by muse, mutect2, varscan2
- XIRP2 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs776835140, COSV54685480, COSV99739101; called by muse, varscan2
- XIRP2 | c.9777G>A p.M3259I (on ENST00000628543; = p.M3434I on NM_152381.6) | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV54685507; called by mutect2, varscan2
- YTHDC2 | c.2248C>T p.R750C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs745327872, COSV50736964; called by mutect2, varscan2
- ZCCHC17 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.503); catalogued as rs775062343, COSV60001423; called by muse, mutect2, varscan2
- ZFHX3 | c.8795G>A p.G2932E | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51710395; called by muse, mutect2, varscan2
- ZIM3 | c.154A>T p.T52S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV54140466; called by muse, mutect2, varscan2
- ZNF146 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100757687, COSV61931272; called by muse, mutect2, varscan2
- ZNF17 | c.1138C>T p.H380Y | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56920821; called by muse, mutect2, varscan2
- ZNF19 | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV55507039; called by muse, mutect2, varscan2
- ZNF224 | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV100425362; called by mutect2, varscan2
- ZNF415 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.327); catalogued as COSV54699345; called by mutect2, varscan2
- ZNF470 | c.63T>C p.G21= | Splice Region (SNP) | VAF 18/64 reads (28%) | catalogued as COSV57967794; called by muse, mutect2, varscan2
- ZNF479 | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1183624164, COSV58636387; called by muse, varscan2
- ZNF502 | c.1600C>T p.L534F | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV56072660; called by muse, mutect2, varscan2
- ZNF544 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV54134435; called by muse, mutect2, varscan2
- ZNF555 | c.1108T>G p.C370G | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62072844; called by muse, mutect2, varscan2
- ZNF565 | c.1441C>T p.H481Y (on ENST00000355114; = p.H441Y on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58410419; called by muse, varscan2
- ZNF578 | c.1376A>T p.E459V | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV69736029; called by mutect2, varscan2
- ZNF641 | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV56389592, COSV56391116; called by muse, mutect2, varscan2
- ZNF664 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100544443; called by muse, mutect2, varscan2
- ZNF664 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV100544444; called by muse, mutect2, varscan2
- ZNF708 | c.904C>T p.H302Y | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV63606955; called by mutect2, varscan2
- ZNF721 | c.64C>T p.L22F (on ENST00000338977; = p.L34F on NM_133474.4) | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV59089841; called by muse, mutect2, varscan2
- ZNF749 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.99); PolyPhen benign (0.103); catalogued as rs774396329, COSV61945251; called by muse, mutect2, varscan2
- ZNF750 | c.76A>G p.K26E | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53958677; called by muse, mutect2, varscan2
- ZNF793 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.113); catalogued as COSV71324816; called by muse, mutect2, varscan2
- ZNF813 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs200579437, COSV67175947; called by muse, mutect2, varscan2
- ZNF813 | c.1789C>T p.H597Y | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV101124794; called by mutect2, varscan2
- ZNF827 | c.565T>A p.F189I | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65225219; called by mutect2, varscan2
- ZNF831 | c.4771C>T p.P1591S | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.503); catalogued as rs267606026, COSV64037912; called by muse, mutect2, varscan2
- ZNF835 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV73379217; called by muse, mutect2, varscan2
- ZNF99 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.547); catalogued as COSV68054948, COSV68054977; called by muse, mutect2, varscan2
- ZNFX1 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757223213, COSV65573995; called by muse, mutect2, varscan2
- ZPBP | c.592T>A p.L198I | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV50422783; called by muse, mutect2, varscan2
- ZSCAN25 | c.682-1G>A p.X228_splice | Splice Site (SNP) | VAF 50/155 reads (32%) | catalogued as COSV53552171; called by muse, mutect2, varscan2
- ZSWIM2 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV54574046; called by muse, mutect2, varscan2
- ARIH1 | c.524_526del p.M175del | In Frame Del (DEL) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- CERT1 | c.2018_2020del p.V673_R674delinsG (on ENST00000405807 / NM_001130105.1; = p.V545_R546delinsG on NM_005713.3) | In Frame Del (DEL) | VAF 19/80 reads (24%) | called by mutect2, pindel*, varscan2
- CFHR4 | c.1382C>T p.P461L (on ENST00000367416 / NM_001201551.2; = p.P215L on NM_006684.5) | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by mutect2, varscan2
- FAM153B | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- GNAI3 | c.182_183dup p.S62Ifs*11 | Frame Shift Ins (INS) | VAF 13/54 reads (24%) | called by mutect2, pindel, varscan2
- KRTAP10-4 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); called by muse, varscan2
- MAST3 | c.268C>A p.P90T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- PRAMEF10 | c.294G>A p.W98* | Nonsense Mutation (SNP) | VAF 35/205 reads (17%) | called by muse, mutect2, varscan2
- TRAV12-2 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- VAV1 | c.558+1G>A p.X186_splice | Splice Site (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- A2ML1 | c.444C>T p.F148= | Silent (SNP) | VAF 44/114 reads (39%) | catalogued as rs914336844, COSV55286615; called by mutect2, varscan2
365 further variants in this file (0 protein-altering or splice-affecting, 337 silent, 28 other) are not listed here.
